Somatic mutation profile of tumor specimen MP2PRT-PATHSK-TBP1-A (aliquot MP2PRT-PATHSK-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATHSK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (817 days).
Specimen MP2PRT-PATHSK-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 794b922f-2f12-45d8-9631-5986a257ee34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHSK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHSK-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fd771f5-dc36-4f19-86d8-0bd51a10ff8e

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 60/246 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4365G>C p.Q1455H | Missense Mutation (SNP) | VAF 18/502 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54326253, COSV54333390, COSV54337016; called by muse, mutect2
- ARHGEF16 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 30/651 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101000327; called by muse, mutect2
- CACNA1I | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 46/716 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); catalogued as rs1204968393; called by muse, mutect2
- ITGA3 | c.1893C>A p.F631L | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs776971185; called by muse, mutect2
- LGR5 | c.1834G>A p.V612M | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs765873009, COSV57005036; called by muse, mutect2
- SBNO2 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV62322605; called by muse, mutect2, varscan2
- SPOP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 81/405 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV61655928; called by muse, mutect2, varscan2
- SYNE2 | c.9241C>T p.R3081W | Missense Mutation (SNP) | VAF 104/355 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs150085946, COSV100648133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USF3 | c.4829G>C p.R1610T | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57069362; called by muse, mutect2, varscan2
- ZNF462 | c.7144G>A p.D2382N | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1319943624; called by muse, mutect2
- ATP1B1 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- EML5 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FAM50B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2
- FAM89B | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 34/806 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RASA2 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 69/414 reads (17%) | called by muse, mutect2, varscan2
- SLC2A12 | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 52/284 reads (18%) | called by muse, mutect2
- SLCO1B3 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SRGAP1 | c.1771dup p.L591Pfs*4 | Frame Shift Ins (INS) | VAF 38/414 reads (9%) | called by mutect2, pindel
- USF3 | c.5100G>A p.M1700I | Missense Mutation (SNP) | VAF 58/267 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USF3 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BEST3 | c.792C>T p.Y264= | Silent (SNP) | VAF 91/402 reads (23%) | catalogued as rs780570896, COSV58306312; called by muse, mutect2, varscan2
- CRPPA | c.816G>A p.A272= (on ENST00000407010 / NM_001368197.1; = p.A222= on NM_001101417.4) | Silent (SNP) | VAF 40/424 reads (9%) | catalogued as rs754348253; ClinVar: uncertain significance; called by muse, mutect2
- EXOC2 | c.1179G>A p.V393= | Silent (SNP) | VAF 54/276 reads (20%) | called by muse, mutect2, varscan2
- HS3ST6 | c.867C>T p.L289= | Silent (SNP) | VAF 52/740 reads (7%) | catalogued as COSV53535500; called by muse, mutect2
- STRN | c.27C>G p.V9= | Silent (SNP) | VAF 104/505 reads (21%) | called by muse, mutect2, varscan2
- TM7SF3 | c.894C>T p.F298= | Silent (SNP) | VAF 10/253 reads (4%) | called by muse, mutect2
